Somatic mutation profile of tumor specimen MP2PRT-PAVLXF-TMP1-A (aliquot MP2PRT-PAVLXF-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVLXF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (840 days).
Specimen MP2PRT-PAVLXF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c04281d-d309-43a8-b232-7730b6fccc5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLXF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLXF-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93b27d02-a57d-45f2-a108-d831b1ffa2ef

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 145/439 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DMRTA1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57924001; called by muse, mutect2, varscan2
- DMRTA1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 65/107 reads (61%) | catalogued as rs748232506; called by muse, mutect2, varscan2
- HOXC13 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 177/491 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54499256; called by muse, mutect2, varscan2
- KIAA1755 | c.3496C>A p.Q1166K | Missense Mutation (SNP) | VAF 131/496 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99641632; called by muse, mutect2, varscan2
- MMP28 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 191/532 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1555603342; called by muse, mutect2, varscan2
- OBSCN | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 184/499 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs765055309, COSV52780215; called by muse, mutect2, varscan2
- PCNX1 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs373015087, COSV53095227; called by muse, varscan2
- PITPNM2 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99759070; called by mutect2, varscan2
- CMA1 | c.30_31del p.F11Sfs*7 | Frame Shift Del (DEL) | VAF 98/370 reads (26%) | called by pindel, varscan2
- DMRTA1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 212/381 reads (56%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRTA1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 125/220 reads (57%) | called by muse, mutect2, varscan2
- EDC4 | c.3764_3765del p.P1255Lfs*5 | Frame Shift Del (DEL) | VAF 159/606 reads (26%) | called by mutect2, pindel, varscan2
- IGHJ6 | chr14:105863248 TAGTAGTAGTAATCACAA>CCCCCCCGCTG | Missense Mutation (DEL) | VAF 73/127 reads (57%) | called by pindel, varscan2*
- SMCO1 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAJ48 | c.1del p.S2Lfs*8 | Frame Shift Del (DEL) | VAF 46/78 reads (59%) | called by mutect2, pindel*, varscan2
- ZNF277 | c.916T>C p.F306L | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMRTA1 | c.1053C>T p.F351= | Silent (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- DPP7 | c.1233C>T p.I411= | Silent (SNP) | VAF 202/504 reads (40%) | called by muse, mutect2, varscan2
- DST | c.19179G>T p.L6393= (on ENST00000361203 / NM_001374722.1; = p.L4090= on NM_015548.5) | Silent (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- EPHA4 | c.2524C>A p.R842= | Silent (SNP) | VAF 30/284 reads (11%) | catalogued as COSV99917162; called by muse, mutect2, varscan2
- IPO7 | c.-80C>T | 5'UTR (SNP) | VAF 146/605 reads (24%) | called by muse, mutect2, varscan2
